TCGA case TCGA-HW-A5KJ — Brain Lower Grade Glioma (TCGA-LGG)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: MSKCC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8996dc64-8c5e-4e07-8ed8-2eb11c03626b

Demographics
Sex at birth: male; Race: white; Country of residence at enrollment: United States; Age at index: 68 years; Vital status: Dead; Days to death: 962 days (2.6 years).

Diagnoses (2)
1. Oligodendroglioma, anaplastic (the primary disease): ICD-O-3 morphology code: 9451/3; ICD-10 code: C71.0; Tissue or organ of origin: Cerebrum; Site of resection or biopsy: Nervous system, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 68.4 years (24,966 days); Year of diagnosis: 2012; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 962 days (2.6 years); Sites of involvement: Brain, Frontal lobe; Supratentorial localization: White Matter.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Days to treatment start: 16 days; Days to treatment end: 16 days; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 107 days; Days to treatment end: 169 days; Treatment dose: 60 Gy; Treatment outcome: Stable Disease; Number of fractions: 30; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Temozolomide; Days to treatment start: 656 days (1.8 years); Days to treatment end: 899 days (2.5 years); Treatment outcome: Stable Disease.
   Recorded as not given: Radiation Therapy, NOS to Head, Face or Neck, NOS, prior to diagnosis; Steroid Therapy, preoperative.
2. Recurrence of diagnosis 1 (Oligodendroglioma, anaplastic). Age at diagnosis: 70.0 years (25,581 days); Days to diagnosis: 615 days (1.7 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 615 days (1.7 years); Treatment anatomic sites: Locoregional Site.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS; Surgery, NOS to Distant Site.

Follow-up (5 entries)
- Days to follow up: 321 days; Disease response: With Tumor.
- Day 615 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 615 days (1.7 years).
- Days to follow up: 619 days (1.7 years); Disease response: With Tumor.
- Days to follow up: 860 days (2.4 years); Disease response: With Tumor.
- Days to follow up: 962 days (2.6 years); Disease response: With Tumor.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-HW-A5KJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 640 mg.
  Slide TCGA-HW-A5KJ-01A-01-TSA: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 90; Percent normal cells: 5; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-HW-A5KJ-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-HW-A5KJ-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Central nervous system; Histologic diagnosis: Oligodendroglioma; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; History ionizing radiation to head: No; Tumor status: With tumor; Tumor site: Supratentorial, Frontal Lobe; History seizures: No; History neoadjuvant steroid treatment: No.
- Drug treatment 1: Treatment best response: Clinical Progressive Disease.
- Follow-up form 1: Lost to follow-up: No; New tumor event surgery: Yes; Tumor status: With tumor; New tumor event pharmaceutical treatment: No; New tumor event radiation treatment: No; New tumor event surgery met: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 962 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 962 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 615 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-HW-A5KJ-01A-12D-A27J-01): tumor purity 0.82, ploidy 1.96, whole-genome doublings 0.
